Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-6599, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-6599-01A (Primary Tumor).

The patient is a [REDACTED] status-post AAA repair, status-post exploratory laparotomy [REDACTED]
PRE OP DIAGNOSIS: Ischemic bowel.
POST OP DIAGNOSIS: Same.
PROCEDURE: Exploratory laparotomy.

FINAL DIAGNOSIS:

Collection Date: [REDACTED]

COLON, TOTAL COLECTOMY -

- A. INVASIVE WELL DIFFERENTIATED ADENOCARCINOMA OF (6.2 CM), ARISING IN A TUBULOVILLOUS ADENOMA INVADING INTO THE MUSCULARIS PROPRIA.
B. NO ANGIOLYMPHATIC OR PERINEURAL INVASION NOTED.
C. SURGICAL MARGINS OF RESECTION FREE OF TUMOR.
D. TWENTY-FIVE (25) PERICOLIC LYMPH NODES FREE OF TUMOR.
E. PATHOLOGICAL STAGE: T2, N0, MX. DUKE'S STAGE: A.
F. ASTLER-COLLER STAGE B1.
G. SMALL TUBULAR ADENOMAS.
H. WELL-DIFFERENTIATED APPENDICEAL CARCINOID (0.2 CM) (see comment).

COMMENT:

The adenocarcinoma which is focally mucin producing, invades entire thickness of the muscle wall and abuts but does not invade adjacent subserosal fat.

The incidental carcinoid of the vermiform appendix is located mostly in the sumucosa and does not show mitoses or necrosis.

SYNOPTIC - PRIMARY COLON AND RECTAL TUMORS

- A. Location: 1
1. Ileocecal Region
2. Ascending Colon
3. Transverse Colon
4. Descending Colon
5. Sigmoid Colon
6. Rectum
- B. Procedure: 2
1. Segmental Colectomy
2. Total Colectomy
3. Other
- C. Size of Tumor (maximum dimension): 6.0 cm
- D. Type: 2
1. Adenocarcinoma, NOS
2. Adenocarcinoma arising in a background of an adenoma.
3. Adenocarcinoma arising in a background of inflammatory bowel disease
4. Adenosquamous carcinoma
5. Carcinoid Tumor (Neuroendocrine Tumor)
6. Mucinous Adenocarcinoma
7. Signet ring cell type Adenocarcinoma
8. Neuroendocrine Carcinoma
9. Squamous Cell Carcinoma
10. Undifferentiated Carcinoma
11. Sarcoma
12. Smooth Muscle Tumor
13. Gastrointestinal stromal tumor
14. Lymphoma
15. Other
- E. Grade: 2
1. Well differentiated
2. Moderately differentiated
3. Poorly differentiated
- F. Extent of Infiltration: 3
1. Limited to the mucosa
2. Into submucosa
3. Involving muscularis propria
4. Infiltrating through muscularis propria into serosal adipose tissue
5. Involving adjacent organs/ pelvic wall
- G. Angiolymphatic Invasion: 2
1. Yes
2. No
- H. Surgical Margins Involved: 2
1. Yes
2. No
- I. Regional Lymph Node Involvement: 2
1. Yes
2. No
- J. If regional lymph nodes involved, Number positive/number examined: 0 / 25.
- K. Extracapsular spread: 2
Yes
2. No.
- L. Associated conditions. N / A
1. Ulcerative colitis.
2. Crohns Disease.
3. History/ presence of adenomatous polyps.
4. Multiple polyposis syndromes.
5. Diverticulosis.
- M. TNM Stage: T 2 N 0 M X
- N. Dukes' Stage: 1
1. A (limited to mucosa and muscularis)
2. B (through muscularis into subserosa)
3. C (through subserosa and involving adjacent organ/pelvic wall/regional or distant lymph nodes)
- O. Astler - Coller Stage: 2
1. A (mucosa but not into muscularis propria)
2. B1 (muscularis propria but not through, LN negative)
3. B2 (through muscularis propria into subserosal fibroadipose tissue, LN negative)
4. C1 (limited to muscularis propria but not through serosa, LN positive)
5. C2 (invades serosal adipose tissue, LN positive)

Source: NCI Genomic Data Commons file 9543fd41-1d60-46e9-92f6-eefc7c904664 (TCGA-AZ-6599.6FF86694-0E1F-4119-9FA2-36789C237D74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).